CGCI case BLGSP-71-30-00777 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1dfe8874-42c5-4653-8e19-c02ca7d90946

Demographics
Sex at birth: male; Age at index: 43 years; Vital status: Alive.

Diagnoses (1)
1. Burkitt lymphoma, NOS (Includes all variants): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Classification of tumor: primary; Age at diagnosis: 43.8 years (16,006 days); Year of diagnosis: 2009; Method of diagnosis: Incisional Biopsy; Ann Arbor B symptoms: No; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 4,279 days (11.7 years); Ann Arbor extranodal involvement: Yes; Max tumor bulk site: Mandible; Sites of involvement: Mandible.
   Pathology details: Bone marrow malignant cells: No.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Days to treatment start: 6 days; Days to treatment end: 67 days.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis.

Follow-up (1 entry)
- Follow-up contacts recording only the day: day -382, day 0, day 3,398, day 4,279.

Molecular and laboratory tests
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- FMC-7 (IHC): Positive; Specialized molecular test: FMC-7.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- Lactate Dehydrogenase 316 [Blood test normal range upper: 230].

Other clinical attributes
- Day -382: Risk factors: HIV/AIDS.
- Day -382: Comorbidities: HIV/AIDS.
- Day 0: Comorbidities: Hepatitis C Infection.
- Day 0: Risk factors: Hepatitis C Infection.
- Day 0: Cdc hiv risk factors: Intravenous Drug User.
- Day 0: Weight: 78.5 kg; Height: 170 cm; BMI: 27.2; CD4 count: 210; HIV viral load: 217.
- Day 4,279: Nadir CD4 count: 100.

Biospecimens (2 samples)
- Sample BLGSP-71-30-00777-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00777-01Z: Sample type: Tumor; Tissue type: Tumor.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Lost to follow-up: No; New tumor event diagnosis indicator: No.
- History of disease: Cdc HIV risk group: IV drug user.
- History of disease, History relevant infectious diseases: History relevant infectious diagnosis: Hepatitis C.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Lymph nodes examined: No.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: No Known Nodal Involvement.
- Stage record, Ann arbor: B symptoms present indicator: No.
- Tests performed: LDH level: 316; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic testing results, Genetic testing result 3: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 4: Immunophenotypic analysis tested: CD10.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: FMC7.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result: Genetic abnormality tested: C-myc.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes.
